Somatic mutation profile of tumor specimen TCGA-EE-A2GU-06A (aliquot TCGA-EE-A2GU-06A-11D-A196-08) from TCGA case TCGA-EE-A2GU, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 70.0 years (25,563 days).
Specimen TCGA-EE-A2GU-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7fc11106-6491-43f4-93f7-324902f438e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GU-10A (Blood Derived Normal), aliquot TCGA-EE-A2GU-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e2bb5bf-7542-47df-b39e-e0c9b443faab

The open-access MAF lists 701 somatic variants for this specimen: 450 protein-altering or splice-affecting, 231 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 411, Silent 231, Nonsense Mutation 25, Intron 8, Splice Region 6, RNA 6, Splice Site 5, 3'Flank 3, Frame Shift Ins 2, 5'Flank 1, Translation Start Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARL16 | c.16G>A p.G6R | Missense Mutation (SNP) | VAF 12/39 reads (31%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs768772097, COSV61266597; called by muse, mutect2, varscan2
- COL4A5 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886074, CM074112, CM107331, COSV60355987; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRNKL1 | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 61/125 reads (49%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1057519885, COSV55618331; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- IDH1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 17/74 reads (23%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.1); catalogued as rs121913499, CM1111831, COSV61615256, COSV61615456, COSV61615649; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LIFR | c.2074C>T p.R692* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | catalogued as rs199775294, CM148257, COSV54684377; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 37/119 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- PTEN | c.1026+1G>C p.X342_splice | Splice Site (SNP) | VAF 4/44 reads (9%) | hotspot (GDC flag); catalogued as rs786201041, CS043794, CS110216, COSV64288702, COSV64289135, COSV64293873; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- A1CF | c.1207G>A p.A403T (on ENST00000373993 / NM_138932.2; = p.A395T on NM_014576.4) | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.172); catalogued as COSV50957135; called by muse, mutect2, varscan2
- ABCB1 | c.1184G>A p.R395K | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55944998; called by muse, mutect2, varscan2
- ABCD3 | c.1336C>T p.P446S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1422985096, COSV100931345; called by muse, mutect2, varscan2
- ABCD3 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100931346, COSV100931454; called by muse, mutect2, varscan2
- AC100868.1 | c.1912G>A p.E638K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.168); catalogued as COSV51837726; called by muse, mutect2, varscan2
- ACO2 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); catalogued as rs746995807, COSV53440919; called by muse, mutect2, varscan2
- ACTA1 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs878854387, COSV64202862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTA2 | c.349A>G p.N117D | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.779); catalogued as COSV56515611; called by muse, mutect2, varscan2
- ACTN2 | c.1107+1G>A p.X369_splice | Splice Site (SNP) | VAF 10/48 reads (21%) | catalogued as COSV63971858; called by muse, mutect2
- ADAMTS18 | c.860G>A p.G287E | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.64); PolyPhen benign (0.045); catalogued as COSV51398661; called by muse, mutect2, varscan2
- ADAMTS20 | c.2221C>T p.P741S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67126003; called by muse, mutect2, varscan2
- ADAMTS6 | c.1858C>T p.R620* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as rs1267132639, COSV66856691; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3328G>A p.G1110R | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.041); catalogued as rs146998252; called by muse, mutect2, varscan2
- ADGRA2 | c.1793C>T p.T598I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV59440726; called by muse, mutect2, varscan2
- ADGRE1 | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 72/284 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV51671890; called by muse, mutect2, varscan2
- ADGRE3 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.831); catalogued as COSV53728286, COSV53734828; called by muse, mutect2, varscan2
- ADGRV1 | c.1687G>A p.G563R | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV67978301; called by muse, mutect2, varscan2
- AHCYL2 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61485029, COSV61490197; called by muse, mutect2, varscan2
- AHNAK2 | c.3137T>G p.L1046R | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as COSV60907472; called by muse, mutect2, varscan2
- AKR1C4 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54122237; called by muse, mutect2, varscan2
- ALDH1L1 | c.1154G>A p.G385E | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0.005); catalogued as rs567886270, COSV56410563; called by muse, mutect2, varscan2
- ALDH5A1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267600900, COSV62372745; called by muse, mutect2, varscan2
- ALMS1 | c.6845C>T p.P2282L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52502551; called by muse, mutect2, varscan2
- ALPK3 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as COSV51929160; called by muse, mutect2, varscan2
- AMPH | c.1547C>T p.T516I | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV57732702; called by muse, mutect2, varscan2
- ANAPC1 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.979); catalogued as rs746437990, COSV61974184; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4616C>T p.P1539L | Missense Mutation (SNP) | VAF 53/171 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.255); catalogued as COSV51840411; called by muse, mutect2, varscan2
- ANKRD42 | c.1040A>T p.H347L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52614322; called by muse, mutect2, varscan2
- ANKS1B | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61334647; called by muse, mutect2, varscan2
- ANXA3 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.751); catalogued as rs1299838799, COSV53713102; called by muse, mutect2, varscan2
- APLNR | c.134G>A p.G45D | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57241364; called by muse, mutect2, varscan2
- APOB | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 180/647 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV51922910; called by muse, mutect2, varscan2
- AQR | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV50029552; called by muse, mutect2, varscan2
- ARID4B | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.108); catalogued as COSV51598095; called by muse, mutect2, varscan2
- ARNTL2 | c.1891G>A p.D631N | Missense Mutation (SNP) | VAF 71/127 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.566); catalogued as COSV53823309; called by muse, mutect2, varscan2
- ASB4 | c.1223C>T p.S408F | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV57942622; called by muse, mutect2, varscan2
- ATAD2B | c.2461C>T p.R821C | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.988); catalogued as rs778701503, COSV53195041; called by muse, mutect2, varscan2
- ATP10D | c.2518C>T p.R840C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760054397, COSV56703712; called by muse, mutect2, varscan2
- ATP13A4 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV55065869; called by muse, mutect2, varscan2
- ATP1A3 | c.2516C>T p.P839L (on ENST00000545399 / NM_001256214.2; = p.P826L on NM_152296.5) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57485014; called by muse, mutect2, varscan2
- ATP4A | c.496A>C p.T166P | Missense Mutation (SNP) | VAF 52/147 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52865467; called by muse, mutect2, varscan2
- ATP8B4 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs761255490, COSV52709008; called by muse, mutect2, varscan2
- ATP9A | c.1120C>T p.R374C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs756587295, COSV58762895, COSV58762969; called by muse, mutect2, varscan2
- B3GALT1 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs746868901, COSV59908017; called by muse, mutect2, varscan2
- BCL9L | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1157752576, COSV52688644; called by muse, mutect2, varscan2
- BCL9L | c.1348C>T p.P450S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs766714909, COSV52681750, COSV99418874; called by muse, mutect2, varscan2
- BRINP2 | c.2198C>T p.P733L | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.36); catalogued as rs1393068413, COSV64175213; called by muse, mutect2, varscan2
- BRINP3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs367647063, COSV66531909; called by muse, mutect2, varscan2
- C1orf198 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 100/296 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.366); catalogued as COSV64174473; called by muse, mutect2, varscan2
- C22orf42 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV66075211; called by muse, mutect2, varscan2
- C3AR1 | c.532C>T p.L178F | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV50817453; called by muse, mutect2, varscan2
- C6orf118 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV57812422; called by muse, mutect2, varscan2
- C8A | c.94G>A p.A32T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV63483059; called by muse, mutect2, varscan2
- CABS1 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs747783679, COSV56732918, COSV56734268; called by muse, mutect2, varscan2
- CABYR | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 28/113 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59110158; called by muse, mutect2, varscan2
- CARMIL2 | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV58022968; called by muse, mutect2, varscan2
- CASR | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as COSV56134140; called by muse, mutect2, varscan2
- CCBE1 | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.024); catalogued as COSV67949165; called by muse, mutect2, varscan2
- CCDC158 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.051); catalogued as COSV63092402; called by muse, mutect2, varscan2
- CCDC181 | c.754C>T p.P252S | Missense Mutation (SNP) | VAF 56/128 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV63155637; called by muse, mutect2, varscan2
- CCDC74A | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT tolerated (0.32); PolyPhen benign (0.301); catalogued as rs145934024, COSV54605168; called by muse, mutect2, varscan2
- CCT8L2 | c.1246G>A p.E416K | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63461624, COSV63463703; called by muse, mutect2, varscan2
- CD163L1 | c.2540G>A p.G847E | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV58010794, COSV58025502; called by muse, varscan2
- CD163L1 | c.2469T>A p.D823E | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV58010801; called by muse, varscan2
- CD2BP2 | c.589C>T p.Q197* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as rs766956859, COSV59768112; called by muse, mutect2, varscan2
- CD300LD | c.352G>A p.V118I | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.046); catalogued as COSV60083296; called by muse, mutect2, varscan2
- CD48 | c.654C>T p.A218= | Splice Region (SNP) | VAF 26/108 reads (24%) | catalogued as COSV63565936; called by muse, mutect2, varscan2
- CDH17 | c.2035C>T p.P679S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50325598, COSV50343298; called by muse, mutect2, varscan2
- CDH8 | c.1201C>T p.H401Y | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.699); catalogued as COSV54847817; called by muse, mutect2, varscan2
- CEACAM5 | c.2039C>T p.S680F | Missense Mutation (SNP) | VAF 179/549 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV55750537; called by muse, mutect2, varscan2
- CEP89 | c.1544C>T p.S515L | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV59862041; called by muse, mutect2, varscan2
- CETN1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV59120846; called by muse, mutect2, varscan2
- CFAP300 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.669); catalogued as rs267602669, COSV71570580, COSV71571017; called by muse, mutect2, varscan2
- CHAD | c.152A>T p.E51V | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.911); catalogued as COSV99366092; called by muse, mutect2, varscan2
- CHCHD3 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV99365791; called by muse, mutect2, varscan2
- CHCHD5 | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.992); catalogued as rs765150422, COSV100260802; called by muse, mutect2, varscan2
- CHD9 | c.5675C>T p.S1892F | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV54607565; called by muse, mutect2, varscan2
- CHP2 | c.416T>C p.V139A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV55649153; called by muse, mutect2, varscan2
- CLCNKA | c.1167G>A p.W389* | Nonsense Mutation (SNP) | VAF 31/111 reads (28%) | catalogued as rs1408156970, COSV100510033, COSV58890376; called by muse, mutect2, varscan2
- CNTN5 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54280074; called by muse, mutect2, varscan2
- CNTNAP2 | c.1085G>A p.G362E | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as COSV62144663, COSV62167074; called by muse, mutect2, varscan2
- COL21A1 | c.2102G>A p.G701E | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55152222; called by muse, mutect2, varscan2
- COL5A2 | c.1565G>A p.G522D | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66407016; called by muse, mutect2, varscan2
- COL5A3 | c.2417G>A p.G806E | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53406043; called by muse, mutect2, varscan2
- COL7A1 | c.4229C>T p.P1410L | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs1417358926, COSV60391009; called by muse, mutect2, varscan2
- CPED1 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.57); PolyPhen benign (0.028); catalogued as COSV59997025; called by muse, mutect2, varscan2
- CR1 | c.5387G>A p.G1796E | Missense Mutation (SNP) | VAF 85/236 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267598342, COSV65455741; called by muse, mutect2, varscan2
- CRACDL | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.134); catalogued as rs1001053916, COSV67406441; called by muse, mutect2, varscan2
- CRB1 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0.04); catalogued as rs564754426, COSV66328611; called by muse, mutect2, varscan2
- CRHBP | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 120/381 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57187520; called by muse, mutect2, varscan2
- CRIM1 | c.2186C>T p.S729F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99752782; called by muse, mutect2, varscan2
- CRISPLD2 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 55/151 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs1437734188, COSV52276641; called by muse, mutect2, varscan2
- CSMD2 | c.1949G>A p.G650E | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868169530, COSV53878136; called by muse, mutect2, varscan2
- CTR9 | c.1607G>A p.R536H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs966128559, COSV63727761; called by muse, mutect2, varscan2
- CUX1 | c.3680C>T p.S1227F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as rs753062642, COSV52890922; called by muse, mutect2, varscan2
- CXorf21 | c.611C>T p.P204L | Missense Mutation (SNP) | VAF 37/94 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV66762397; called by muse, mutect2, varscan2
- CYBA | c.236T>A p.L79Q | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.478); catalogued as COSV55367776; called by muse, mutect2, varscan2
- CYP11B2 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.199); catalogued as COSV100010983, COSV59994417; called by muse, mutect2, varscan2
- CYP1A2 | c.1468G>A p.D490N | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs763531887, COSV59659020; called by muse, mutect2, varscan2
- CYP21A2 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 64/385 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.041); catalogued as rs150804717; called by muse, mutect2, varscan2
- CYP2C9 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs562386989, COSV53246350; called by muse, mutect2, varscan2
- CYP2S1 | c.238G>A p.V80I | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.061); catalogued as COSV59505007; called by muse, mutect2, varscan2
- CYP4F3 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV55407005; called by muse, mutect2, varscan2
- DAB2IP | c.2921C>T p.S974F (on ENST00000408936; = p.S946F on NM_032552.3) | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV52254435; called by muse, mutect2, varscan2
- DECR1 | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 30/137 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs867052303, COSV55166675; called by muse, mutect2, varscan2
- DHX36 | c.88C>T p.H30Y | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.018); catalogued as COSV57670845; called by muse, mutect2, varscan2
- DHX9 | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV62358175; called by muse, mutect2, varscan2
- DIPK2B | c.1233G>T p.R411S | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV67640824; called by muse, mutect2, varscan2
- DIRAS2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65369957; called by muse, mutect2, varscan2
- DISP3 | c.1636C>T p.H546Y | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV53820122; called by muse, mutect2, varscan2
- DMXL1 | c.4648C>T p.H1550Y | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.957); catalogued as rs998972537, COSV60704697; called by muse, mutect2, varscan2
- DNAH17 | c.12714G>A p.M4238I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53143270; called by muse, mutect2, varscan2
- DNAH5 | c.8881G>A p.G2961R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54203613; called by mutect2, varscan2
- DNAH5 | c.5776G>A p.E1926K | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs771222700, COSV54202729, COSV99454399; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.2944C>T p.R982C | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.15); catalogued as rs143673459; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.5764-1G>A p.X1922_splice | Splice Site (SNP) | VAF 8/24 reads (33%) | catalogued as COSV56751522; called by muse, mutect2, varscan2
- DNAH7 | c.3733C>T p.H1245Y | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867382316, COSV56750907; called by muse, mutect2, varscan2
- DNAJB13 | c.859A>G p.K287E | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV60104273; called by muse, mutect2, varscan2
- DPEP3 | c.1403C>T p.P468L | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV99262609; called by muse, mutect2, varscan2
- DSC3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs757290041, COSV64571675; called by muse, mutect2, varscan2
- DSCAM | c.5408C>T p.S1803F | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1454321096, COSV68020692; called by muse, mutect2, varscan2
- DSCAM | c.4720C>T p.P1574S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV68020696; called by muse, mutect2, varscan2
- DSG4 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57388185; called by muse, mutect2, varscan2
- DYM | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as rs756877451, COSV53980097; called by muse, mutect2, varscan2
- ENAM | c.1241G>A p.G414E | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.248); catalogued as rs867796122, COSV68535183; called by muse, mutect2, varscan2
- EOMES | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1559925811, COSV55410990; called by muse, mutect2, varscan2
- ERICH3 | c.3125G>A p.R1042K | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs761301934, COSV58598944; called by muse, mutect2, varscan2
- ERN1 | c.1709C>T p.S570F | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV70500344; called by muse, mutect2, varscan2
- ERO1A | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs866974289, COSV67470670; called by muse, mutect2, varscan2
- FAM110B | c.140G>A p.R47K | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0.151); catalogued as COSV64063183; called by muse, mutect2, varscan2
- FAM47C | c.2546C>T p.S849L | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.151); catalogued as COSV63723575; called by muse, mutect2, varscan2
- FAM83B | c.1988G>A p.R663Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as rs766774691, COSV60919265; called by muse, mutect2, varscan2
- FAT3 | c.2167C>T p.P723S | Missense Mutation (SNP) | VAF 164/590 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53074815; called by muse, mutect2, varscan2
- FBH1 | c.338C>T p.S113L (on ENST00000362091 / NM_178150.3; = p.S164L on NM_032807.4) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as COSV62981506; called by muse, mutect2, varscan2
- FBXW10 | c.2558G>A p.R853K | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.931); catalogued as COSV100111274; called by muse, mutect2, varscan2
- FCN2 | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV52475843; called by muse, mutect2, varscan2
- FEM1A | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 31/84 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV54162964; called by muse, mutect2, varscan2
- FGF12 | c.563G>A p.R188K (on ENST00000454309 / NM_021032.5; = p.R126K on NM_004113.6) | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.191); catalogued as COSV53151914, COSV53164870; called by muse, mutect2, varscan2
- FMN2 | c.3241C>T p.P1081S | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.043); catalogued as COSV60460340; called by muse, varscan2
- FPR3 | c.419G>A p.S140N | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.17); PolyPhen benign (0.071); catalogued as rs762807147, COSV59328212; called by muse, mutect2, varscan2
- FYB2 | c.1754T>A p.I585N | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV58582855; called by muse, varscan2
- FYB2 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 59/163 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV58582867; called by muse, mutect2, varscan2
- GBE1 | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV70096859; called by muse, mutect2, varscan2
- GCM1 | c.1068G>A p.W356* | Nonsense Mutation (SNP) | VAF 34/111 reads (31%) | catalogued as COSV52520768; called by muse, mutect2, varscan2
- GIMAP5 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs769621407, COSV57529643; called by muse, mutect2, varscan2
- GIMAP7 | c.123A>C p.Q41H | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57958361; called by muse, mutect2, varscan2
- GLYAT | c.50C>T p.S17F | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.5); catalogued as COSV53538375; called by muse, mutect2, varscan2
- GPA33 | c.29G>A p.W10* | Nonsense Mutation (SNP) | VAF 22/69 reads (32%) | catalogued as COSV54801929; called by muse, mutect2, varscan2
- GPC6 | c.34C>T p.L12F | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV65497066; called by muse, mutect2, varscan2
- GPR162 | c.568G>A p.G190R | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV50589067; called by muse, mutect2, varscan2
- GRIA3 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.768); catalogued as COSV52049101; called by muse, mutect2, varscan2
- GRK3 | c.1445C>T p.A482V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.841); catalogued as COSV60793232; called by muse, mutect2, varscan2
- GRK4 | c.1195G>A p.D399N (on ENST00000398052 / NM_182982.3; = p.D367N on NM_005307.3) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as rs771111205, COSV61667967, COSV61668059; called by muse, mutect2, varscan2
- GRXCR2 | c.401C>A p.T134N | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV65060651; called by muse, mutect2, varscan2
- GSAP | c.566G>A p.G189E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.069); catalogued as COSV57528200, COSV57528405; called by muse, mutect2, varscan2
- HCN4 | c.881C>T p.P294L | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV56081277; called by muse, mutect2, varscan2
- HIP1 | c.2572C>T p.P858S | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.043); catalogued as COSV61183150, COSV61187387; called by muse, mutect2, varscan2
- HIVEP3 | c.2048C>T p.P683L | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs768164975, COSV56009571; called by muse, mutect2, varscan2
- HPR | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.732); catalogued as COSV57181465; called by muse, mutect2, varscan2
- IGFN1 | c.3325G>A p.E1109K (on ENST00000295591 / NM_001367841.1; = p.E3566K on NM_001164586.2) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as rs1408149566, COSV55165682; called by muse, mutect2, varscan2
- IGSF10 | c.3245C>G p.P1082R | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.618); catalogued as COSV56781497, COSV99213320; called by muse, mutect2, varscan2
- IKBKE | c.1597C>T p.Q533* | Nonsense Mutation (SNP) | VAF 13/75 reads (17%) | catalogued as COSV65624276; called by muse, mutect2, varscan2
- IL10RB | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.973); catalogued as rs1321425844, COSV51614050; called by muse, mutect2, varscan2
- IL10RB | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as COSV99269832; called by muse, mutect2, varscan2
- IL18RAP | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.107); catalogued as COSV51823875; called by muse, mutect2, varscan2
- IL7R | c.1238G>A p.S413N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.012); catalogued as rs756406426, COSV57405697; called by muse, mutect2, varscan2
- ILF3 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV51554083; called by muse, mutect2, varscan2
- INPP5B | c.1917G>A p.G639= (on ENST00000373023; = p.G559= on NM_005540.3 and 3 other RefSeq transcripts) | Splice Region (SNP) | VAF 15/93 reads (16%) | catalogued as rs768949615, COSV65959376; called by muse, mutect2, varscan2
- INPP5D | c.1684T>C p.F562L (on ENST00000445964 / NM_001017915.3; = p.F561L on NM_005541.5) | Missense Mutation (SNP) | VAF 46/168 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.302); catalogued as COSV64035358; called by muse, mutect2, varscan2
- IPCEF1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs1250920211, COSV54540473, COSV99499905; called by muse, mutect2, varscan2
- IQCJ | c.388C>T p.L130F | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.005); catalogued as rs1306212976, COSV101188157, COSV67331076; called by muse, mutect2, varscan2
- IRF7 | c.1480T>C p.C494R (on ENST00000397566; = p.C481R on NM_001572.5) | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs1245545649, COSV52750947; called by muse, mutect2, varscan2
- ITGA2 | c.815G>A p.R272Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as rs756548150, COSV56856274; called by muse, mutect2
- ITGA4 | c.1528C>T p.P510S | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as COSV51997767; called by muse, mutect2, varscan2
- ITGA6 | c.639G>A p.W213* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV51219209; called by muse, mutect2, varscan2
- ITGB6 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs750398020, COSV51790735, COSV51795910; called by muse, mutect2, varscan2
- KBTBD7 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as COSV65266054; called by muse, mutect2, varscan2
- KCNN3 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1485181152, COSV55212412, COSV99679453; called by muse, mutect2, varscan2
- KCNQ5 | c.2036C>T p.S679L | Missense Mutation (SNP) | VAF 52/101 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV59649042; called by muse, mutect2, varscan2
- KCNS2 | c.1291G>A p.D431N | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs994439138, COSV54637187; called by muse, mutect2, varscan2
- KEL | c.1288G>A p.A430T | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV62333187; called by muse, mutect2, varscan2
- KIAA0319 | c.2736T>C p.G912= | Splice Region (SNP) | VAF 9/57 reads (16%) | catalogued as COSV65496204; called by muse, mutect2, varscan2
- KIF16B | c.3314C>G p.A1105G | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV61701223; called by muse, mutect2, varscan2
- KIF26A | c.3800C>T p.S1267F | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.086); catalogued as COSV59464465; called by muse, mutect2, varscan2
- KIF4B | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.405); catalogued as COSV70527788; called by muse, mutect2, varscan2
- KRT81 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as rs772604686, COSV59809009; called by muse, mutect2, varscan2
- KRT9 | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 63/234 reads (27%) | catalogued as COSV55851527; called by muse, mutect2, varscan2
- LAD1 | c.1134G>A p.M378I | Missense Mutation (SNP) | VAF 68/139 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV66212033; called by muse, mutect2, varscan2
- LAMB3 | c.943A>G p.R315G | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV61915217; called by muse, mutect2, varscan2
- LARS1 | c.2091-1G>A p.X697_splice (on ENST00000394434 / NM_020117.11; = p.X670_splice on NM_016460.3) | Splice Site (SNP) | VAF 7/51 reads (14%) | catalogued as COSV50972178; called by muse, mutect2
- LARS1 | c.1850G>A p.G617E (on ENST00000394434 / NM_020117.11; = p.G590E on NM_016460.3) | Missense Mutation (SNP) | VAF 80/290 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); catalogued as COSV50972187; called by muse, mutect2, varscan2
- LCE1B | c.65C>T p.P22L | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.801); catalogued as COSV63980046; called by muse, mutect2, varscan2
- LCE4A | c.163G>A p.G55R | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.714); catalogued as COSV59266281; called by muse, mutect2, varscan2
- LEMD3 | c.2159T>C p.V720A | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV57648389; called by muse, mutect2, varscan2
- LFNG | c.656A>T p.H219L (on ENST00000222725 / NM_001040167.2; = p.H90L on NM_002304.2) | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.161); catalogued as COSV56068543; called by muse, mutect2, varscan2
- LILRB4 | c.1289C>T p.P430L (on ENST00000391733 / NM_001278428.3; = p.P429L on NM_001278426.3) | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.073); catalogued as COSV54403393; called by muse, mutect2, varscan2
- LMAN2 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 70/218 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57423735; called by muse, mutect2, varscan2
- LNPEP | c.1577C>T p.S526L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV51476137; called by muse, mutect2, varscan2
- LPAR2 | c.271C>T p.H91Y | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV52554119; called by muse, mutect2
- LRFN2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.98); PolyPhen benign (0.121); catalogued as rs759803528, COSV57823733; called by muse, mutect2, varscan2
- LRRC47 | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65561939; called by muse, mutect2, varscan2
- LRRC4C | c.1522C>T p.P508S | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.316); catalogued as COSV53417978, COSV53434364; called by muse, mutect2, varscan2
- LRWD1 | c.758C>T p.S253L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs575719006, COSV52960349; called by muse, mutect2, varscan2
- LTBP3 | c.1963G>A p.G655R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.243); catalogued as rs770990142, COSV100099233; called by muse, mutect2, varscan2
- MAGEC3 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 39/86 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV53576062; called by muse, mutect2, varscan2
- MAP1A | c.7171G>A p.G2391R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55806010; called by muse, mutect2, varscan2
- MAP3K19 | c.2858C>T p.S953F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV59636546; called by muse, mutect2, varscan2
- MAP3K21 | c.2345C>T p.S782F | Missense Mutation (SNP) | VAF 29/161 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV64041001; called by muse, mutect2, varscan2
- MAU2 | c.1780C>T p.P594S | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV53233552; called by muse, mutect2, varscan2
- MCTP1 | c.740G>A p.G247E | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV56503865; called by muse, mutect2, varscan2
- MDGA1 | c.199C>T p.R67* | Nonsense Mutation (SNP) | VAF 11/71 reads (15%) | catalogued as rs1020346548, COSV51791696, COSV99776803; called by muse, mutect2, varscan2
- MEGF8 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52074915; called by muse, mutect2, varscan2
- MEOX2 | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100012606, COSV56287486; called by muse, mutect2, varscan2
- MERTK | c.2968G>A p.D990N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.216); catalogued as rs200644454, COSV54924407; called by muse, mutect2, varscan2
- MICAL2 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56316351; called by muse, mutect2, varscan2
- MKLN1 | c.1747C>T p.P583S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as COSV61759951; called by muse, mutect2, varscan2
- MNDA | c.682C>G p.P228A | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV63739861, COSV63740905; called by muse, mutect2, varscan2
- MPP7 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61729954; called by muse, mutect2, varscan2
- MROH2B | c.1424G>A p.R475K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.98); catalogued as COSV68180917; called by muse, mutect2, varscan2
- MRPS28 | c.553C>T p.H185Y | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.044); catalogued as COSV52561056; called by muse, mutect2, varscan2
- MRTFA | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); catalogued as COSV62931183; called by muse, mutect2, varscan2
- MTOR | c.673C>T p.P225S | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100815834, COSV63879884; called by muse, mutect2, varscan2
- MUC16 | c.42283G>A p.G14095S | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.997); catalogued as COSV66689763; called by muse, mutect2, varscan2
- MUC16 | c.40707G>A p.W13569* | Nonsense Mutation (SNP) | VAF 66/193 reads (34%) | catalogued as COSV66689770, COSV66690405; called by muse, mutect2, varscan2
- MUC16 | c.39755G>A p.R13252K | Missense Mutation (SNP) | VAF 31/128 reads (24%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.455); catalogued as COSV66689774, COSV66694501; called by muse, mutect2, varscan2
- MUC16 | c.22994C>T p.S7665F | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.011); catalogued as rs577405018, COSV67444187; called by muse, mutect2, varscan2
- MUC16 | c.17183C>T p.S5728F | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs866944888, COSV67444191, COSV67500083; called by muse, mutect2, varscan2
- MUC16 | c.8399G>A p.G2800E | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as COSV67444199; called by muse, mutect2, varscan2
- MUC16 | c.7036G>A p.E2346K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.039); catalogued as rs1211609182, COSV67444208, COSV67464032; called by muse, mutect2, varscan2
- MYH4 | c.4672G>A p.E1558K | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs1366396326, COSV55112072; called by muse, mutect2, varscan2
- MYO16 | c.3062G>A p.R1021K | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.056); catalogued as COSV62745184; called by muse, mutect2, varscan2
- MYO18B | c.3477G>A p.M1159I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.33); PolyPhen benign (0.012); catalogued as rs1418121616, COSV59125061; called by muse, mutect2, varscan2
- MYO3B | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV58694141; called by muse, mutect2, varscan2
- MYO3B | c.3427G>A p.G1143R | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs372432679; called by muse, mutect2, varscan2
- MYO5C | c.4525C>T p.Q1509* | Nonsense Mutation (SNP) | VAF 13/43 reads (30%) | catalogued as COSV55902478; called by muse, mutect2, varscan2
- MYO7B | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs770751834, COSV67344446; called by muse, mutect2, varscan2
- MYO9B | c.1301T>G p.V434G | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV68276935; called by muse, mutect2, varscan2
- NCOA6 | c.4067T>C p.L1356P | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV62861294; called by muse, mutect2, varscan2
- NCOR2 | c.5072C>T p.T1691I | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62292997; called by muse, mutect2, varscan2
- NDRG4 | c.244C>T p.Q82* (on ENST00000570248 / NM_001378344.1; = p.Q114* on NM_020465.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 43/133 reads (32%) | catalogued as COSV50746349; called by muse, mutect2, varscan2
- NEK2 | c.392G>A p.S131N | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV65355168; called by muse, mutect2, varscan2
- NEK9 | c.436A>T p.K146* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV53129243; called by muse, mutect2, varscan2
- NEU2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52091559; called by muse, mutect2, varscan2
- NFIA | c.431G>A p.S144N | Missense Mutation (SNP) | VAF 34/116 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV64533653; called by muse, mutect2, varscan2
- NFXL1 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.018); catalogued as COSV61197984; called by muse, mutect2, varscan2
- NLRP5 | c.182C>T p.S61F | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV66761986; called by muse, mutect2, varscan2
- NSUN6 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as rs867410434, COSV66031726; called by muse, mutect2, varscan2
- NSUN7 | c.1028G>A p.G343E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.774); catalogued as COSV57272517; called by muse, mutect2, varscan2
- NT5C1A | c.558G>A p.G186= | Splice Region (SNP) | VAF 10/39 reads (26%) | catalogued as COSV52493092; called by muse, mutect2, varscan2
- NTRK3 | c.1868G>A p.G623E | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62295522; called by muse, mutect2, varscan2
- NUP210L | c.1507G>A p.E503K | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.182); catalogued as COSV55141416, COSV99667231; called by muse, mutect2, varscan2
- OGDHL | c.2605C>T p.R869W | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); catalogued as rs375570156, COSV65101274; called by muse, mutect2, varscan2
- OLFML3 | c.1099C>T p.R367C | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs374722221; called by muse, mutect2, varscan2
- OPALIN | c.92G>A p.G31E | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV64520316; called by muse, mutect2, varscan2
- OPRPN | c.406C>T p.P136S | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen possibly damaging (0.495); catalogued as rs867803285, COSV68192566; called by muse, mutect2, varscan2
- OR10G3 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV57809626; called by muse, mutect2, varscan2
- OR10H5 | c.928C>T p.L310F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV58277396; called by muse, mutect2
- OR11G2 | c.287C>T p.P96L | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776200418, COSV62131745; called by muse, mutect2, varscan2
- OR2L13 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 179/304 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs1220270755, COSV63547893, COSV63554410; called by muse, mutect2, varscan2
- OR4C13 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 61/249 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV73648620; called by muse, mutect2, varscan2
- OR4K13 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV59858953; called by muse, mutect2, varscan2
- OR4K2 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 39/430 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53847918, COSV53848106; called by muse, mutect2
- OR4Q3 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 48/392 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV59177262, COSV59177487; called by muse, mutect2, varscan2
- OR51B5 | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs531142715, COSV56174887; called by muse, mutect2, varscan2
- OR52B4 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.333); catalogued as rs778991316, COSV68768572; called by muse, mutect2, varscan2
- OR52E2 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as rs267602936, COSV58611784; called by muse, mutect2, varscan2
- OR8D2 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770491562, COSV62488032, COSV62488391; called by muse, mutect2, varscan2
- OR8K3 | c.500C>T p.S167F | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.25); catalogued as rs867380056, COSV57130753; called by muse, mutect2, varscan2
- OSBPL10 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67336142; called by muse, mutect2, varscan2
- OSM | c.514dup p.A172Gfs*122 | Frame Shift Ins (INS) | VAF 8/37 reads (22%) | catalogued as rs762184254; called by mutect2, pindel, varscan2
- OSMR | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as COSV57080892; called by muse, mutect2, varscan2
- OVGP1 | c.826G>A p.G276R | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as rs1277989834, COSV63857493; called by muse, mutect2, varscan2
- PAQR3 | c.385T>A p.S129T | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.191); catalogued as COSV55008409; called by muse, mutect2, varscan2
- PARD3 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60745051; called by muse, mutect2, varscan2
- PCARE | c.3149C>T p.P1050L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as COSV59052984; called by muse, mutect2, varscan2
- PCDH1 | c.3161C>T p.S1054F | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs761384407, COSV54610829; called by mutect2, varscan2
- PCDHA4 | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 23/92 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.909); catalogued as rs267600386, COSV63538765; called by muse, mutect2, varscan2
- PCDHB1 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1554267555, COSV60629428; called by muse, varscan2
- PCDHGB6 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as rs1035756303, COSV53897747, COSV54025291; called by muse, mutect2, varscan2
- PCNX2 | c.3454C>T p.P1152S | Missense Mutation (SNP) | VAF 16/108 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50781631, COSV50798457; called by muse, mutect2, varscan2
- PCSK5 | c.5434G>A p.D1812N | Missense Mutation (SNP) | VAF 63/239 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as COSV70447046; called by muse, mutect2, varscan2
- PDCD4 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54521763; called by muse, mutect2, varscan2
- PDE8A | c.2188C>T p.P730S | Missense Mutation (SNP) | VAF 56/115 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59634744; called by muse, mutect2, varscan2
- PDS5A | c.3206C>T p.S1069F | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV57822351; called by muse, mutect2, varscan2
- PEG10 | c.656C>T p.S219F (on ENST00000482108 / NM_001040152.2; = p.S253F on NM_015068.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.094); catalogued as COSV71787958; called by muse, mutect2, varscan2
- PEG3 | c.4456G>A p.G1486R | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs759827815, COSV55624459; called by muse, mutect2, varscan2
- PEG3 | c.1615G>A p.E539K | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV55624470; called by muse, mutect2, varscan2
- PGM2 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.036); catalogued as COSV67938297; called by muse, mutect2, varscan2
- PHKA2 | c.2123G>T p.G708V | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV66052471; called by muse, mutect2, varscan2
- PID1 | c.357G>A p.W119* (on ENST00000354069 / NM_001330156.1; = p.W117* on NM_017933.5) | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as COSV62472458, COSV62481819; called by muse, mutect2, varscan2
- PIWIL1 | c.214C>T p.Q72* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV55343990; called by muse, mutect2, varscan2
- PLA2G4D | c.989G>A p.G330E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1322859282, COSV51819038; called by muse, mutect2, varscan2
- PLA2G7 | c.766G>A p.E256K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1244402138, COSV51258389; called by muse, mutect2, varscan2
- PLEKHG2 | c.2377G>A p.D793N | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as rs748160123, COSV52678215; called by muse, mutect2
- PLEKHG2 | c.4105G>A p.E1369K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.007); catalogued as rs369622702; called by muse, mutect2, varscan2
- PLEKHG4B | c.2807C>T p.P936L (on ENST00000283426; = p.P1292L on NM_052909.5) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52043357; called by muse, mutect2, varscan2
- PM20D1 | c.71G>A p.R24K | Missense Mutation (SNP) | VAF 45/110 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1390509674, COSV65648398; called by muse, mutect2, varscan2
- POF1B | c.154G>A p.V52M | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53130199, COSV53133792; called by muse, mutect2, varscan2
- POU6F2 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV68867435; called by muse, mutect2, varscan2
- PPARA | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV53076872; called by muse, mutect2, varscan2
- PPFIA4 | c.2105C>T p.P702L (on ENST00000447715; = p.P703L on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV55311213; called by muse, mutect2, varscan2
- PPP1R3A | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.724); catalogued as COSV52876050, COSV99494765; called by muse, mutect2, varscan2
- PRAMEF12 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as rs1383590063, COSV63214676; called by muse, mutect2, varscan2
- PRDM1 | c.2347G>A p.G783R | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs1342455675, COSV64844350; called by muse, mutect2, varscan2
- PREX2 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV55750317; called by muse, mutect2, varscan2
- PRPF8 | c.5845C>T p.R1949W | Missense Mutation (SNP) | VAF 82/137 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs778682568, COSV59260510; called by muse, mutect2, varscan2
- PRSS36 | c.1787C>T p.P596L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51635700; called by muse, mutect2, varscan2
- PSD | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated, low confidence (0.29); PolyPhen possibly damaging (0.879); catalogued as COSV50041745; called by muse, mutect2, varscan2
- PTGFR | c.901C>T p.P301S | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557660883, COSV66114307; called by muse, mutect2, varscan2
- PTPRB | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54232063; called by muse, mutect2, varscan2
- PTPRF | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as COSV63442445; called by muse, mutect2, varscan2
- PXK | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as COSV57086479; called by muse, mutect2, varscan2
- RABEP2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs947884284, COSV62868436; called by muse, mutect2, varscan2
- RANBP17 | c.2453C>T p.S818L | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs774534368, COSV66644253; called by muse, mutect2, varscan2
- RAPGEF4 | c.1073C>T p.S358F | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51379265, COSV51418766; called by muse, mutect2, varscan2
- RASAL1 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV55653759; called by muse, mutect2, varscan2
- RASAL2 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.722); catalogued as COSV62709419; called by muse, mutect2, varscan2
- RASEF | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV64585793; called by muse, mutect2, varscan2
- REG4 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 192/608 reads (32%) | SIFT tolerated (0.41); PolyPhen benign (0.045); catalogued as rs150927973; called by muse, mutect2, varscan2
- RELN | c.9886G>A p.G3296R | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV58985525; called by muse, mutect2, varscan2
- RNF17 | c.4786G>A p.E1596K | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs762834742, COSV55033740; called by muse, mutect2, varscan2
- RYR3 | c.10545G>A p.W3515* (on ENST00000389232; = p.W3516* on NM_001036.6) | Nonsense Mutation (SNP) | VAF 7/24 reads (29%) | catalogued as COSV66777492; called by muse, mutect2, varscan2
- SACS | c.11368C>T p.Q3790* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV66534021; called by muse, mutect2, varscan2
- SACS | c.5153C>T p.S1718F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV66533704; called by muse, mutect2, varscan2
- SALL1 | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs866692687, COSV51753059; called by muse, mutect2, varscan2
- SAMD9L | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.436); catalogued as COSV59079386; called by muse, mutect2, varscan2
- SAV1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as rs761235120, COSV61204299; called by muse, mutect2, varscan2
- SCN11A | c.1465C>T p.Q489* | Nonsense Mutation (SNP) | VAF 24/77 reads (31%) | catalogued as COSV56565565; called by muse, mutect2, varscan2
- SCN4A | c.5241G>A p.M1747I | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV71125561; called by muse, mutect2, varscan2
- SCN5A | c.4172G>A p.G1391E (on ENST00000333535 / NM_198056.3; = p.G1390E on NM_000335.5) | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.205); catalogued as COSV61115574, COSV61120094; called by muse, mutect2, varscan2
- SCRIB | c.4724C>T p.S1575F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.61); PolyPhen possibly damaging (0.789); catalogued as rs782291991, COSV57582114; called by muse, mutect2, varscan2
- SCRIB | c.401C>T p.A134V | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57582128; called by muse, mutect2, varscan2
- SDK2 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV66181112, COSV66197024; called by muse, mutect2, varscan2
- SDR16C5 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV58125310; called by muse, mutect2, varscan2
- SEPHS2 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.21); PolyPhen benign (0.022); catalogued as rs749127994, COSV72100703; called by muse, mutect2, varscan2
- SGCG | c.280G>A p.E94K | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as rs867039495, COSV54555841; called by muse, mutect2, varscan2
- SHMT2 | c.596C>T p.P199L | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.318); catalogued as COSV61073138; called by muse, mutect2, varscan2
- SIGLEC12 | c.1247G>A p.G416E (on ENST00000291707 / NM_053003.4; = p.G298E on NM_033329.2) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV52459243, COSV52465931; called by muse, mutect2, varscan2
- SIGLEC5 | c.881C>T p.S294F | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.19); catalogued as COSV55777349; called by muse, mutect2, varscan2
- SLAMF8 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 146/292 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.254); catalogued as rs769173999, COSV56987500; called by muse, mutect2, varscan2
- SLC10A2 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs370357133, COSV55357044; called by muse, mutect2, varscan2
- SLC35F3 | c.127G>A p.A43T (on ENST00000366617 / NM_001300845.1; = p.A112T on NM_173508.4) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as COSV64018195; called by muse, mutect2, varscan2
- SLC35F3 | c.907G>A p.G303R (on ENST00000366617 / NM_001300845.1; = p.G372R on NM_173508.4) | Missense Mutation (SNP) | VAF 94/259 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.024); catalogued as COSV64018200; called by muse, mutect2, varscan2
- SLC47A1 | c.1522G>A p.D508N | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs746812934, COSV54498856; called by muse, mutect2, varscan2
- SLC4A1 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.314); catalogued as rs142195740; called by muse, mutect2, varscan2
- SLC4A11 | c.2632G>A p.E878K | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.053); catalogued as COSV66260295; called by muse, mutect2, varscan2
- SLC5A6 | c.1003C>T p.Q335* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV60158361, COSV60160505; called by muse, mutect2, varscan2
- SLCO4C1 | c.1952G>A p.G651E | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as COSV60512705; called by muse, mutect2, varscan2
- SLCO5A1 | c.770G>A p.G257E | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.97); catalogued as COSV52653520; called by muse, mutect2, varscan2
- SLFN11 | c.1138C>G p.P380A | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.905); catalogued as COSV57697363, COSV57699593; called by muse, mutect2
- SLFN13 | c.1072C>T p.P358S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1165895053, COSV53192216; called by muse, mutect2, varscan2
- SLFN13 | c.983C>T p.P328L | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53192226; called by muse, mutect2, varscan2
- SLMAP | c.1325C>T p.S442F (on ENST00000428312 / NM_001377924.1; = p.S463F on NM_007159.5) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.674); catalogued as COSV55844405; called by muse, mutect2, varscan2
- SMTNL1 | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); catalogued as COSV67699087; called by muse, mutect2, varscan2
- SMURF2 | c.1418C>T p.S473F | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52312656; called by muse, mutect2, varscan2
- SNTG2 | c.877C>T p.P293S | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1248389475, COSV57967880; called by muse, mutect2, varscan2
- SOX13 | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65826200; called by muse, mutect2, varscan2
- SPATA16 | c.849G>A p.R283= | Splice Region (SNP) | VAF 26/91 reads (29%) | catalogued as rs1286747984, COSV63526456; called by muse, mutect2, varscan2
- SPATA21 | c.505G>A p.G169S | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0.011); catalogued as COSV59185161; called by muse, mutect2, varscan2
- SPDYC | c.379G>A p.G127S | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV65864881; called by muse, mutect2, varscan2
- SREBF2 | c.966G>T p.Q322H | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.962); catalogued as COSV63330434; called by muse, mutect2, varscan2
- STAC | c.497G>A p.G166E | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1051920712, COSV56206504; called by muse, mutect2, varscan2
- STAG3 | c.1669G>C p.G557R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.119); catalogued as COSV57927440; called by muse, mutect2, varscan2
- STK33 | c.304C>T p.P102S | Missense Mutation (SNP) | VAF 39/143 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs751636788, COSV59396378; called by muse, mutect2, varscan2
- STXBP5L | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV56527178; called by muse, mutect2, varscan2
- SV2C | c.179C>T p.P60L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs758651691, COSV59213838; called by muse, mutect2, varscan2
- SYT3 | c.1281+1G>A p.X427_splice | Splice Site (SNP) | VAF 7/21 reads (33%) | catalogued as COSV58895432; called by mutect2, varscan2
- TBC1D17 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV55576977; called by muse, mutect2, varscan2
- TBC1D8B | c.2097T>G p.D699E | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.994); catalogued as COSV52175679; called by muse, mutect2, varscan2
- TCF23 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 62/237 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs138845716; called by muse, mutect2, varscan2
- TCHH | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 86/362 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV64272729; called by muse, mutect2, varscan2
- TCHHL1 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as rs1457625350; called by muse, mutect2, varscan2
- TDRD6 | c.4496C>T p.S1499F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.156); catalogued as rs761838172, COSV60173827; called by muse, mutect2, varscan2
- TGM6 | c.279G>A p.M93I | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs999608768, COSV52477310; called by muse, mutect2, varscan2
- THSD1 | c.1019C>T p.T340I | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs987547620, COSV51626411; called by muse, mutect2, varscan2
- TIAM1 | c.4232C>A p.S1411Y | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as COSV54536785, COSV54537243; called by muse, mutect2, varscan2
- TLL1 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); catalogued as rs1411322301, COSV50261775; called by muse, mutect2, varscan2
- TLR4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV62922416; called by muse, mutect2, varscan2
- TMC2 | c.602G>A p.G201E | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62649693; called by muse, mutect2, varscan2
- TMEM108 | c.442G>A p.G148R | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV58864143; called by muse, mutect2, varscan2
- TMEM132A | c.2303C>T p.P768L (on ENST00000453848 / NM_178031.3; = p.P769L on NM_017870.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.719); catalogued as rs1190936180, COSV50000449; called by muse, mutect2, varscan2
- TMEM132D | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.708); catalogued as COSV67158697; called by muse, mutect2, varscan2
- TMEM255B | c.194G>A p.G65D | Missense Mutation (SNP) | VAF 33/100 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759131103, COSV64703403; called by muse, mutect2, varscan2
- TMEM53 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); catalogued as COSV62404656; called by muse, mutect2, varscan2
- TMSB10 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.635); catalogued as COSV99252787; called by muse, mutect2, varscan2
- TNFRSF13B | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.444); catalogued as COSV55426555; called by muse, mutect2, varscan2
- TNR | c.2872G>A p.D958N | Missense Mutation (SNP) | VAF 27/54 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV54869792; called by muse, mutect2, varscan2
- TPO | c.2552C>T p.S851F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV61094377; called by muse, mutect2, varscan2
- TRBV24-1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.668); catalogued as rs750318009; called by muse, mutect2, varscan2
- TRHR | c.1024A>G p.T342A | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1323635744, COSV61232767; called by muse, mutect2, varscan2
- TRIM26 | c.1570C>T p.P524S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70982436; called by muse, mutect2, varscan2
- TRIM49 | c.1066G>A p.G356S | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61670203; called by muse, mutect2, varscan2
- TRIOBP | c.2381C>T p.S794F | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.017); catalogued as COSV60373483; called by muse, mutect2, varscan2
- TRIP12 | c.1232T>G p.L411R | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV52259048; called by muse, mutect2, varscan2
- TRPM4 | c.3038C>T p.S1013F | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV53260128; called by muse, mutect2, varscan2
- TRRAP | c.11294A>G p.K3765R (on ENST00000359863 / NM_001244580.1; = p.K3736R on NM_003496.3) | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV62815734; called by muse, mutect2, varscan2
- TSSK1B | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.405); catalogued as COSV66814765; called by muse, mutect2, varscan2
- TTLL10 | c.1173G>A p.M391I (on ENST00000379289 / NM_001130045.2; = p.M318I on NM_153254.3) | Missense Mutation (SNP) | VAF 103/311 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.069); catalogued as COSV64959386; called by muse, mutect2, varscan2
- TTN | c.62335G>A p.E20779K (on ENST00000591111; = p.E13355K on NM_003319.4) | Missense Mutation (SNP) | VAF 49/154 reads (32%) | PolyPhen benign (0.415); catalogued as rs530426755, COSV59883596; called by muse, mutect2, varscan2
- TTN | c.11881C>T p.P3961S (on ENST00000591111; = p.P3915S on NM_003319.4) | Missense Mutation (SNP) | VAF 7/38 reads (18%) | catalogued as COSV100600540; called by muse, mutect2, varscan2
- TTYH1 | c.735G>C p.V245= | Splice Region (SNP) | VAF 31/113 reads (27%) | catalogued as COSV56609623; called by muse, mutect2, varscan2
- TUBGCP6 | c.1785A>G p.I595M | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.377); catalogued as rs1409897713, COSV50536468; called by muse, mutect2, varscan2
- UBR4 | c.11494G>A p.D3832N | Missense Mutation (SNP) | VAF 102/336 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV64382748; called by muse, mutect2, varscan2
- UGT2A3 | c.1409G>A p.G470E | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52358752; called by muse, mutect2, varscan2
- UGT2B4 | c.642G>A p.M214I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV59315207; called by muse, mutect2, varscan2
- UNC5CL | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.034); catalogued as COSV55108962; called by muse, mutect2, varscan2
- UNC5D | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.356); catalogued as COSV54769077, COSV99775938; called by muse, mutect2, varscan2
- UNC79 | c.7738C>T p.Q2580* (on ENST00000393151 / NM_001346218.2; = p.Q2403* on NM_020818.5) | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV56373510; called by muse, mutect2, varscan2
- UNC80 | c.886G>A p.D296N | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.104); catalogued as COSV55883348; called by muse, mutect2, varscan2
- USH2A | c.12589G>A p.G4197R | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs745929525, COSV56326821; called by muse, mutect2, varscan2
- USH2A | c.3635C>T p.P1212L | Missense Mutation (SNP) | VAF 41/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM080593, COSV56326842; called by muse, mutect2, varscan2
- USP29 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.034); catalogued as rs754632293, COSV54139849, COSV54147173; called by muse, mutect2, varscan2
- VAV1 | c.2387G>A p.R796Q | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752656112, COSV58378481; called by muse, mutect2, varscan2
- VPS13C | c.8359G>A p.E2787K (on ENST00000644861 / NM_020821.3; = p.E2744K on NM_017684.5) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51121215; called by muse, mutect2, varscan2
- VPS13D | c.3921G>A p.M1307I | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.54); PolyPhen benign (0.022); catalogued as rs1348999781, COSV50621588; called by muse, mutect2, varscan2
- VPS35 | c.976G>A p.D326N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1191997787, COSV54476901; called by muse, mutect2, varscan2
- VWA7 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 87/412 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV63304183; called by muse, mutect2, varscan2
- WFDC6 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV100323139; called by muse, mutect2, varscan2
- WNK2 | c.4010C>T p.S1337F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs760269476, COSV52930829; called by muse, mutect2, varscan2
- XDH | c.3007C>T p.P1003S | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65146839; called by muse, mutect2, varscan2
- XIRP2 | c.2699A>C p.E900A (on ENST00000628543; = p.E1075A on NM_152381.6) | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV54682236; called by muse, mutect2, varscan2
- XIRP2 | c.6005A>G p.D2002G (on ENST00000628543; = p.D2177G on NM_152381.6) | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV54682247; called by muse, mutect2, varscan2
- XKR6 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58654398; called by muse, mutect2, varscan2
- ZAN | c.2641C>T p.P881S | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.007); catalogued as rs781718781, COSV61804916; called by muse, mutect2, varscan2
- ZC3H7A | c.1551T>G p.Y517* | Nonsense Mutation (SNP) | VAF 32/68 reads (47%) | catalogued as COSV63268408; called by muse, mutect2, varscan2
- ZDBF2 | c.1687C>T p.R563W | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs771789452, COSV65621821; called by muse, mutect2, varscan2
- ZDBF2 | c.2123C>T p.S708F | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65621831, COSV65622861; called by muse, mutect2, varscan2
- ZNF148 | c.1039C>A p.P347T | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as COSV62302192; called by muse, mutect2, varscan2
- ZNF18 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 157/244 reads (64%) | SIFT tolerated (0.27); PolyPhen benign (0.031); catalogued as COSV100503038, COSV59550526; called by muse, mutect2, varscan2
- ZNF385B | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV61175013; called by muse, mutect2, varscan2
- ZNF569 | c.1378C>T p.H460Y | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57593519; called by muse, mutect2, varscan2
- ZNF594 | c.1952C>T p.P651L | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV68384690; called by muse, mutect2, varscan2
- ZNF662 | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV60240928; called by muse, mutect2, varscan2
- ZNF749 | c.1666T>C p.Y556H | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61945107; called by muse, mutect2, varscan2
- ZNF831 | c.2875G>A p.G959R | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs1178321673, COSV64037244; called by muse, mutect2, varscan2
- ZNF98 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV63334347; called by muse, mutect2, varscan2
- GPR179 | c.5570G>A p.G1857E (on ENST00000621958; = p.G1856E on NM_001004334.4) | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- H2AC1 | c.229dup p.T77Nfs*15 | Frame Shift Ins (INS) | VAF 24/116 reads (21%) | called by mutect2, varscan2
- IGBP1P2 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- IGLV2-18 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 84/327 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- IGLV3-22 | c.257G>A p.G86E | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- TRAV41 | c.200C>T p.S67F | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.018); called by muse, mutect2
- TRAV9-1 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCC11 | c.1470C>T p.I490= | Silent (SNP) | VAF 42/127 reads (33%) | catalogued as rs139456533; called by muse, mutect2, varscan2
- AC127029.3 | c.465C>T p.I155= | Silent (SNP) | VAF 67/252 reads (27%) | catalogued as COSV60110241; called by muse, mutect2, varscan2
- ACTR1B | c.408C>T p.A136= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as COSV56703091; called by muse, mutect2, varscan2
- ADCY4 | c.3114C>T p.S1038= | Silent (SNP) | VAF 23/80 reads (29%) | catalogued as COSV60251901; called by muse, mutect2, varscan2
- ADCY8 | c.3042C>T p.I1014= | Silent (SNP) | VAF 25/112 reads (22%) | catalogued as COSV53896069; called by muse, mutect2, varscan2
- ADD1 | c.711C>T p.V237= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as rs370483088, COSV99296091; called by muse, mutect2, varscan2
- ADGRL4 | c.1977C>T p.F659= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV66059132; called by muse, mutect2, varscan2
- ADGRV1 | c.18891G>A p.R6297= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV67978304; called by muse, mutect2, varscan2
- ALG3 | c.693C>T p.A231= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV56610073; called by muse, mutect2, varscan2
- AMIGO3 | c.234C>T p.P78= | Silent (SNP) | VAF 30/92 reads (33%) | catalogued as COSV57537482; called by muse, mutect2, varscan2
- AMY2A | c.1290C>T p.N430= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1322488801; called by mutect2, varscan2
- ANKFN1 | c.342C>T p.F114= | Silent (SNP) | VAF 27/65 reads (42%) | catalogued as rs200633862; called by muse, mutect2, varscan2
- ANXA8 | c.603C>T p.F201= | Silent (SNP) | VAF 28/156 reads (18%) | called by muse, mutect2, varscan2
- APOB | c.12618G>A p.G4206= | Silent (SNP) | VAF 164/544 reads (30%) | catalogued as COSV51922888; called by muse, mutect2, varscan2
- APOB | c.4560G>A p.L1520= | Silent (SNP) | VAF 137/501 reads (27%) | catalogued as COSV51922900; called by muse, mutect2, varscan2
- ARHGEF18 | c.1185C>T p.I395= (on ENST00000359920 / NM_001130955.2; = p.I291= on NM_015318.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/86 reads (38%) | catalogued as rs1396405837, COSV60466933; called by muse, mutect2, varscan2
- ARHGEF5 | c.69C>T p.I23= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV99282662; called by muse, mutect2, varscan2
- ARID1B | c.5313C>T p.F1771= | Silent (SNP) | VAF 56/104 reads (54%) | catalogued as rs760729997, COSV51648425; called by muse, mutect2, varscan2
- ARMC4 | c.1677C>T p.I559= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs182410357, COSV100536483, COSV100537387; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARSA | c.586C>T p.L196= | Silent (SNP) | VAF 35/124 reads (28%) | catalogued as COSV53349844; called by muse, mutect2, varscan2
- ASH1L | c.5013C>T p.S1671= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs947482011, COSV64205374; called by muse, mutect2, varscan2
- BACH1 | c.150C>T p.S50= | Silent (SNP) | VAF 21/87 reads (24%) | catalogued as rs753679298, COSV54517325; called by muse, mutect2, varscan2
- BAIAP2 | c.789C>T p.S263= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV58333141; called by muse, mutect2, varscan2
- BCAR1 | c.1929C>T p.F643= | Silent (SNP) | VAF 30/86 reads (35%) | catalogued as COSV50778683; called by muse, mutect2, varscan2
- BOLL | c.453G>A p.E151= | Silent (SNP) | VAF 12/40 reads (30%) | catalogued as COSV56573080; called by muse, mutect2, varscan2
- BPGM | c.489G>A p.E163= | Silent (SNP) | VAF 17/77 reads (22%) | catalogued as COSV61323814; called by muse, mutect2, varscan2
- C6 | c.561C>T p.I187= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as COSV54704768; called by muse, mutect2, varscan2
- CACNA1B | c.6639C>T p.F2213= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs200850551, COSV53113428; called by muse, mutect2, varscan2
- CACNA1C | c.2016C>T p.L672= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV59696436; called by muse, mutect2, varscan2
- CACNA1E | c.5752C>T p.L1918= | Silent (SNP) | VAF 161/360 reads (45%) | catalogued as COSV62381960; called by muse, mutect2, varscan2
- CADM3 | c.957C>T p.P319= (on ENST00000368125 / NM_001127173.3; = p.P353= on NM_021189.5) | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as COSV63675458; called by muse, mutect2, varscan2
- CAPN13 | c.1944C>T p.L648= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV54428332; called by muse, mutect2, varscan2
- CARM1 | c.762C>T p.I254= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV58998881; called by muse, mutect2, varscan2
- CBL | c.201G>A p.V67= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs1195793980, COSV50629899; called by muse, mutect2, varscan2
- CD5 | c.756G>A p.R252= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs1412839005, COSV61717745; called by muse, mutect2, varscan2
- CDYL | c.177C>T p.P59= | Silent (SNP) | VAF 35/93 reads (38%) | catalogued as rs770374434, COSV61036358; called by muse, mutect2, varscan2
- CEACAM16 | c.748C>T p.L250= | Silent (SNP) | VAF 149/473 reads (32%) | catalogued as COSV69186099; called by muse, mutect2, varscan2
- CEP85L | c.1794C>T p.P598= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1001000797, COSV63820705; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.153A>G p.L51= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV51591036; called by muse, mutect2, varscan2
- CHAD | c.153G>A p.E51= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs138853066; called by muse, mutect2, varscan2
- CLCN1 | c.1023C>T p.F341= | Silent (SNP) | VAF 29/131 reads (22%) | catalogued as rs1351015503, COSV58367288; called by muse, mutect2, varscan2
- CLEC4M | c.204C>T p.I68= | Silent (SNP) | VAF 36/114 reads (32%) | catalogued as COSV50216746; called by muse, mutect2, varscan2
- CLPS | c.12C>T p.I4= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs771434902, COSV52565768; called by muse, mutect2, varscan2
- CLTCL1 | c.3966C>T p.I1322= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as COSV54225010; called by muse, mutect2, varscan2
- COL28A1 | c.156C>T p.I52= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs370084753; called by muse, mutect2, varscan2
- COL7A1 | c.5646C>T p.I1882= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV60391003; called by muse, mutect2, varscan2
- CPAMD8 | c.1890C>T p.F630= (on ENST00000651564; = p.F583= on NM_015692.5) | Silent (SNP) | VAF 41/106 reads (39%) | catalogued as rs776271256, COSV52230579; called by muse, mutect2, varscan2
- CSH2 | c.582G>A p.K194= | Silent (SNP) | VAF 51/167 reads (31%) | catalogued as COSV61080001; called by muse, mutect2, varscan2
- CTNNA2 | c.1269G>A p.E423= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV58134117; called by muse, mutect2, varscan2
- CTU2 | c.918C>T p.P306= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as rs768863233, COSV56332995; called by muse, mutect2, varscan2
- CYP2C9 | c.777C>T p.N259= | Silent (SNP) | VAF 15/38 reads (39%) | catalogued as rs747588944, COSV53246355; called by muse, mutect2, varscan2
- DDIT4L | c.330G>A p.V110= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV56766972; called by muse, mutect2, varscan2
- DDX41 | c.12G>A p.S4= | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as COSV57901922; called by muse, mutect2, varscan2
- DENND1A | c.747C>T p.I249= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV101010441; called by muse, mutect2, varscan2
- DNAH5 | c.9957C>T p.I3319= | Silent (SNP) | VAF 46/180 reads (26%) | catalogued as rs766420895, COSV54203577; called by muse, mutect2, varscan2
- DNAH8 | c.6651C>T p.S2217= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as rs775873897, COSV59424278; called by muse, mutect2, varscan2
- DOP1B | c.279C>T p.I93= | Silent (SNP) | VAF 24/97 reads (25%) | catalogued as rs748483414, COSV54279475; called by muse, mutect2, varscan2
- DST | c.3687C>T p.F1229= (on ENST00000361203 / NM_001374722.1; = p.F903= on NM_001723.6) | Silent (SNP) | VAF 15/68 reads (22%) | catalogued as COSV54997203; called by muse, mutect2, varscan2
- DTX1 | c.252G>A p.Q84= | Silent (SNP) | VAF 33/78 reads (42%) | catalogued as rs1412620403, COSV57495590; called by muse, mutect2, varscan2
- EHD3 | c.436C>T p.L146= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as rs1187218923, COSV59029197; called by muse, mutect2, varscan2
- ENPP7 | c.945C>T p.F315= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as rs782708563, COSV60385262; called by muse, mutect2, varscan2
- EPPK1 | c.3381G>A p.Q1127= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV73260794; called by muse, mutect2, varscan2
- ERGIC1 | c.207C>T p.I69= | Silent (SNP) | VAF 31/129 reads (24%) | catalogued as rs1344903435, COSV58595374; called by muse, mutect2, varscan2
- FADS6 | c.753C>T p.H251= | Silent (SNP) | VAF 20/38 reads (53%) | catalogued as COSV59601429; called by muse, mutect2, varscan2
- FAM131B | c.951C>T p.S317= | Silent (SNP) | VAF 36/146 reads (25%) | catalogued as rs766155646, COSV58367291; called by muse, mutect2, varscan2
- FAM83C | c.1356C>T p.L452= | Silent (SNP) | VAF 23/49 reads (47%) | catalogued as COSV65581984; called by muse, mutect2, varscan2
- FAM83F | c.1197G>A p.K399= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs780982282, COSV60999387, COSV61001016; called by muse, mutect2, varscan2
- FBLN2 | c.1983G>A p.L661= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs763522125, COSV55480667; called by muse, mutect2, varscan2
- FBN3 | c.711C>T p.I237= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as COSV54453207; called by muse, mutect2, varscan2
- FBXW10 | c.2559G>A p.R853= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as rs550117830, COSV100111320, COSV57061075; called by muse, mutect2, varscan2
- FCRL4 | c.852C>T p.I284= | Silent (SNP) | VAF 46/105 reads (44%) | catalogued as rs772835672, COSV54859644; called by muse, mutect2, varscan2
- FIGN | c.1701C>T p.I567= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV60762950; called by muse, mutect2, varscan2
- FLNB | c.6555G>A p.V2185= | Silent (SNP) | VAF 28/57 reads (49%) | catalogued as COSV55869957; called by muse, mutect2, varscan2
- FYB2 | c.597C>T p.H199= | Silent (SNP) | VAF 46/162 reads (28%) | catalogued as rs377622948; called by muse, mutect2, varscan2
- FZD5 | c.1287C>T p.I429= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV54942859; called by muse, mutect2, varscan2
- GATM | c.612C>T p.F204= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as COSV67540112; called by muse, mutect2, varscan2
- GCNT3 | c.528C>T p.V176= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV68531948; called by muse, mutect2, varscan2
- GDPD4 | c.354C>T p.I118= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as rs139482139, COSV60017049; called by muse, mutect2, varscan2
- GIMAP1 | c.390G>A p.Q130= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV56187044; called by muse, mutect2, varscan2
- GJB4 | c.405C>T p.L135= | Silent (SNP) | VAF 21/59 reads (36%) | catalogued as rs779192023, COSV58355417; called by muse, mutect2, varscan2
- GLDC | c.447G>A p.R149= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV58676389; called by muse, mutect2, varscan2
- GPATCH2 | c.993C>T p.P331= | Silent (SNP) | VAF 12/100 reads (12%) | catalogued as COSV65127254; called by mutect2, varscan2
- GPR142 | c.711G>A p.L237= | Silent (SNP) | VAF 10/37 reads (27%) | catalogued as COSV100170769, COSV59518525; called by muse, mutect2, varscan2
- GPRC5C | c.1146C>T p.F382= (on ENST00000652232; = p.F337= on NM_018653.4) | Silent (SNP) | VAF 27/73 reads (37%) | catalogued as rs530047993, COSV61235333; called by muse, mutect2, varscan2
- GRIN3A | c.1860C>T p.L620= | Silent (SNP) | VAF 29/76 reads (38%) | catalogued as COSV62450557; called by muse, mutect2, varscan2
- HAUS5 | c.1143C>T p.A381= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV52546532; called by muse, mutect2, varscan2
- HIVEP1 | c.7843C>T p.L2615= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs768963674, COSV65098623; called by muse, mutect2, varscan2
- HLA-G | c.354C>T p.T118= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs748142497, COSV64405113; called by muse, mutect2, varscan2
- HSD17B3 | c.450C>T p.I150= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV64556137; called by muse, mutect2, varscan2
- IFNW1 | c.105G>A p.R35= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV66521786; called by muse, mutect2, varscan2
- IGSF10 | c.1170G>A p.R390= | Silent (SNP) | VAF 10/34 reads (29%) | catalogued as COSV56781504; called by muse, mutect2, varscan2
- IGSF11 | c.555C>T p.L185= (on ENST00000393775 / NM_001015887.3; = p.L184= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as rs1431027891, COSV61165388; called by muse, mutect2, varscan2
- IL1RAPL2 | c.675A>T p.R225= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV61142541; called by muse, mutect2, varscan2
- INSRR | c.2814T>G p.A938= | Silent (SNP) | VAF 18/101 reads (18%) | catalogued as COSV63870872; called by muse, mutect2, varscan2
- JAG1 | c.2952G>A p.R984= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV54753326; called by muse, mutect2, varscan2
- KAT2A | c.1011C>T p.F337= | Silent (SNP) | VAF 49/146 reads (34%) | catalogued as COSV56789200; called by muse, mutect2, varscan2
- KCNK1 | c.817C>T p.L273= | Silent (SNP) | VAF 16/112 reads (14%) | catalogued as COSV64034386; called by muse, mutect2, varscan2
- KCNN4 | c.795C>T p.I265= | Silent (SNP) | VAF 26/87 reads (30%) | catalogued as rs190256118; called by muse, mutect2, varscan2
- KDR | c.2004G>A p.T668= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as rs371966849; called by muse, mutect2, varscan2
- KERA | c.615G>A p.R205= | Silent (SNP) | VAF 36/81 reads (44%) | catalogued as rs747616158, COSV57129864, COSV57130490; called by muse, mutect2, varscan2
- KIR3DL1 | c.1128G>A p.E376= | Silent (SNP) | VAF 54/180 reads (30%) | catalogued as rs1331400604, COSV58489272; called by muse, mutect2, varscan2
- KRT12 | c.1071C>T p.I357= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV52429684, COSV52431594; called by muse, mutect2, varscan2
- KRT16 | c.723C>T p.I241= | Silent (SNP) | VAF 57/144 reads (40%) | catalogued as rs201618706, COSV56966924; called by muse, mutect2, varscan2
- LAMA3 | c.9222C>T p.G3074= (on ENST00000313654 / NM_198129.4; = p.G1465= on NM_000227.6) | Silent (SNP) | VAF 20/120 reads (17%) | catalogued as COSV52529546; called by muse, mutect2
- LAMC2 | c.2370C>T p.L790= | Silent (SNP) | VAF 23/50 reads (46%) | catalogued as rs755154854, COSV51452303; called by muse, mutect2, varscan2
- LCE2C | c.123C>T p.F41= | Silent (SNP) | VAF 85/191 reads (45%) | catalogued as COSV64228239; called by muse, mutect2, varscan2
- LGR6 | c.1581G>A p.L527= (on ENST00000367278 / NM_001017403.1; = p.L475= on NM_021636.3) | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as rs1236913873, COSV55151373; called by muse, mutect2, varscan2
- LMAN1L | c.9G>A p.A3= | Silent (SNP) | VAF 47/107 reads (44%) | catalogued as rs1046314928, COSV59000576; called by muse, mutect2, varscan2
- LTBP2 | c.960C>T p.G320= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV56204715; called by muse, mutect2, varscan2
- LTBP3 | c.1962G>A p.G654= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV100099237; called by muse, mutect2, varscan2
- LY9 | c.312G>A p.L104= | Silent (SNP) | VAF 74/148 reads (50%) | catalogued as COSV54431487; called by muse, mutect2, varscan2
- MAP3K21 | c.1752G>A p.R584= | Silent (SNP) | VAF 10/56 reads (18%) | catalogued as COSV64040994, COSV64041824; called by muse, mutect2, varscan2
- MAPRE2 | c.282C>T p.L94= | Silent (SNP) | VAF 33/102 reads (32%) | catalogued as COSV55817320; called by muse, mutect2, varscan2
- MC2R | c.550C>T p.L184= | Silent (SNP) | VAF 16/78 reads (21%) | catalogued as rs1223534728, COSV59617016; called by muse, mutect2, varscan2
- MCF2 | c.2388G>A p.V796= | Silent (SNP) | VAF 19/52 reads (37%) | catalogued as COSV58477536; called by muse, mutect2, varscan2
- MEOX1 | c.453G>A p.R151= | Silent (SNP) | VAF 85/304 reads (28%) | catalogued as rs868589217, COSV59355219; called by muse, mutect2, varscan2
- MEP1A | c.2235G>A p.R745= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV57917859; called by muse, mutect2, varscan2
- MFN2 | c.1731C>T p.I577= | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs1362979799, COSV52420379; called by muse, mutect2, varscan2
- MFSD1 | c.951C>T p.S317= | Silent (SNP) | VAF 26/71 reads (37%) | catalogued as COSV51838979; called by muse, mutect2, varscan2
- MGA | c.801C>T p.P267= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as rs932998166, COSV54948701; called by muse, mutect2, varscan2
- MICAL3 | c.2382C>T p.C794= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs751101891, COSV52892170; called by muse, mutect2
- MMP20 | c.615C>T p.F205= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as rs752681494, COSV52773785; called by muse, mutect2, varscan2
- MTNR1A | c.762G>A p.L254= | Silent (SNP) | VAF 47/82 reads (57%) | catalogued as COSV56154939; called by muse, mutect2, varscan2
- MUC13 | c.648C>T p.F216= | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as COSV60698462; called by muse, mutect2, varscan2
- MUC16 | c.41697G>A p.R13899= | Silent (SNP) | VAF 56/210 reads (27%) | catalogued as rs1307973167, COSV66689766; called by muse, mutect2, varscan2
- MUC16 | c.27669G>A p.L9223= | Silent (SNP) | VAF 29/100 reads (29%) | catalogued as COSV67444183; called by muse, mutect2, varscan2
- MXRA5 | c.1851G>A p.R617= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as COSV54223580; called by muse, mutect2, varscan2
- MYH15 | c.4560G>A p.E1520= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as COSV56304295; called by muse, mutect2, varscan2
- MYH2 | c.2961G>A p.E987= | Silent (SNP) | VAF 135/249 reads (54%) | catalogued as COSV55431441; called by muse, mutect2, varscan2
- MYO18B | c.7686G>A p.K2562= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as COSV59125065, COSV59130615; called by muse, mutect2, varscan2
- MYPN | c.1722C>T p.P574= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV62731519, COSV62731618; called by muse, mutect2, varscan2
- NAT2 | c.63G>A p.L21= | Silent (SNP) | VAF 40/128 reads (31%) | catalogued as rs1425832493, COSV54061149, COSV99673984; called by muse, mutect2, varscan2
- NAV2 | c.1863C>G p.L621= (on ENST00000396087 / NM_001244963.2; = p.L598= on NM_145117.5) | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as COSV62315123; called by muse, mutect2, varscan2
- NEUROD6 | c.240G>A p.R80= | Silent (SNP) | VAF 50/197 reads (25%) | catalogued as COSV51769940, COSV51773190; called by muse, mutect2, varscan2
- NFASC | c.2238C>T p.I746= (on ENST00000339876 / NM_001378329.1; = p.I742= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as COSV58358563; called by muse, mutect2, varscan2
- NLRC5 | c.3942C>T p.F1314= | Silent (SNP) | VAF 4/28 reads (14%) | catalogued as rs1171264472, COSV52648908; called by muse, mutect2, varscan2
- NLRP11 | c.609C>T p.I203= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs149856648, COSV100789811; called by muse, mutect2, varscan2
- NLRP12 | c.214T>C p.L72= | Silent (SNP) | VAF 57/173 reads (33%) | catalogued as rs1405838629, COSV60743469; called by muse, mutect2, varscan2
- NLRP3 | c.987C>T p.L329= | Silent (SNP) | VAF 30/141 reads (21%) | catalogued as COSV100276446, COSV60219909; called by muse, mutect2, varscan2
- NPAS3 | c.2073C>T p.F691= (on ENST00000356141 / NM_001164749.2; = p.F659= on NM_022123.3) | Silent (SNP) | VAF 29/95 reads (31%) | catalogued as COSV100639878; called by muse, mutect2, varscan2
- NT5C3A | c.246G>A p.T82= (on ENST00000610140 / NM_001374335.1; = p.T48= on NM_016489.13) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs1273900955, COSV54236781; called by muse, mutect2, varscan2
- NUP210L | c.3402G>A p.G1134= | Silent (SNP) | VAF 32/78 reads (41%) | catalogued as rs756851189, COSV55141408; called by muse, mutect2, varscan2
- NXF3 | c.1227G>A p.R409= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as COSV67702609, COSV67703208; called by muse, mutect2, varscan2
- OLFML2B | c.840G>A p.Q280= | Silent (SNP) | VAF 37/97 reads (38%) | catalogued as COSV54193817; called by muse, mutect2, varscan2
- OLFML3 | c.1098C>T p.P366= | Silent (SNP) | VAF 16/61 reads (26%) | catalogued as COSV100233008; called by muse, mutect2, varscan2
- OR13C5 | c.912G>A p.K304= | Silent (SNP) | VAF 15/57 reads (26%) | catalogued as rs372091946, COSV66164136, COSV66164968; called by muse, mutect2, varscan2
- OR1B1 | c.921C>G p.L307= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV59171127; called by muse, mutect2, varscan2
- OR2Y1 | c.309C>T p.I103= | Silent (SNP) | VAF 13/42 reads (31%) | catalogued as COSV57135944; called by muse, mutect2, varscan2
- OR4A47 | c.702C>T p.A234= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as COSV71444838; called by muse, mutect2, varscan2
- OR4X1 | c.486C>T p.F162= | Silent (SNP) | VAF 12/51 reads (24%) | catalogued as COSV60722215; called by muse, mutect2, varscan2
- OR51F2 | c.141C>T p.I47= | Silent (SNP) | VAF 67/212 reads (32%) | catalogued as COSV59063625; called by muse, mutect2, varscan2
- OR51F2 | c.217C>T p.L73= | Silent (SNP) | VAF 43/152 reads (28%) | catalogued as COSV59063669; called by muse, mutect2, varscan2
- OR51I2 | c.531C>T p.S177= | Silent (SNP) | VAF 33/107 reads (31%) | catalogued as COSV58297883; called by muse, mutect2, varscan2
- OR51S1 | c.940T>C p.L314= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as rs745671659, COSV59057203; called by muse, mutect2, varscan2
- OR5D13 | c.885G>A p.R295= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs1295811448, COSV62332673; called by muse, mutect2, varscan2
- OR9K2 | c.549T>A p.I183= (on ENST00000305377; = p.I161= on NM_001005243.1) | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV59531341; called by muse, mutect2, varscan2
- PAPPA2 | c.3711C>T p.P1237= | Silent (SNP) | VAF 23/103 reads (22%) | catalogued as COSV62790516; called by muse, mutect2, varscan2
- PAX4 | c.531C>T p.F177= | Silent (SNP) | VAF 40/122 reads (33%) | catalogued as COSV58387279; called by muse, mutect2, varscan2
- PAX5 | c.936C>T p.L312= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV63905116; called by muse, mutect2, varscan2
- PCDHB1 | c.2130C>T p.F710= | Silent (SNP) | VAF 23/91 reads (25%) | catalogued as COSV60629418; called by muse, mutect2, varscan2
- PCNX2 | c.3540C>T p.F1180= | Silent (SNP) | VAF 34/49 reads (69%) | catalogued as rs753792364, COSV50781615; called by muse, mutect2, varscan2
- PCSK5 | c.3339G>A p.R1113= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs1438021691, COSV70447041; called by muse, mutect2, varscan2
- PDGFB | c.312C>T p.F104= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs757018789, COSV58645713; called by mutect2, varscan2
- PDZD4 | c.285C>T p.V95= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as COSV51245322; called by muse, mutect2, varscan2
- PIANP | c.318C>T p.I106= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs754708575, COSV57707460; called by muse, mutect2, varscan2
- PIK3R5 | c.2442C>T p.P814= | Silent (SNP) | VAF 73/116 reads (63%) | catalogued as COSV52650451; called by muse, mutect2, varscan2
- PLEKHA6 | c.2937G>A p.Q979= | Silent (SNP) | VAF 23/116 reads (20%) | catalogued as COSV55329861; called by muse, mutect2, varscan2
- POP4 | c.591G>T p.G197= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV55675864; called by muse, mutect2, varscan2
- PPM1N | c.1107G>A p.R369= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as COSV55592441; called by muse, mutect2, varscan2
- PPP2R3B | c.1359C>T p.I453= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as COSV66812687; called by muse, mutect2, varscan2
- PRAMEF19 | c.204C>T p.S68= | Silent (SNP) | VAF 48/196 reads (24%) | called by muse, mutect2, varscan2
- PRAMEF2 | c.309G>A p.L103= | Silent (SNP) | VAF 109/361 reads (30%) | catalogued as COSV53572129; called by muse, mutect2, varscan2
- PRKAA2 | c.690C>T p.V230= | Silent (SNP) | VAF 98/314 reads (31%) | catalogued as COSV64801906; called by muse, mutect2, varscan2
- PRR23B | c.729T>A p.G243= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV61493146; called by muse, mutect2, varscan2
- PRR23B | c.420A>G p.E140= | Silent (SNP) | VAF 15/60 reads (25%) | catalogued as COSV100272114, COSV61493153; called by muse, mutect2, varscan2
- PSG3 | c.1137C>T p.L379= | Silent (SNP) | VAF 91/305 reads (30%) | catalogued as rs1476652352, COSV59502362; called by muse, mutect2, varscan2
- PTPRT | c.4227C>T p.I1409= | Silent (SNP) | VAF 34/124 reads (27%) | catalogued as rs1423459994, COSV61959842; called by muse, mutect2, varscan2
- PXDNL | c.648C>T p.L216= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV62477755, COSV62484762; called by muse, mutect2, varscan2
- PXDNL | c.201G>A p.G67= | Silent (SNP) | VAF 18/59 reads (31%) | catalogued as COSV62477761; called by muse, mutect2, varscan2
- RAPGEF5 | c.1593C>T p.V531= (on ENST00000401957 / NM_001367602.2; = p.V834= on NM_012294.5) | Silent (SNP) | VAF 38/123 reads (31%) | catalogued as COSV59778870; called by muse, mutect2, varscan2
- RELN | c.2025C>T p.L675= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV58985537, COSV58993200; called by muse, mutect2, varscan2
- RPGRIP1 | c.2661C>T p.G887= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs779039019, COSV52844517; called by muse, mutect2, varscan2
- RPL18 | c.151T>C p.L51= | Silent (SNP) | VAF 60/208 reads (29%) | catalogued as COSV50031515; called by muse, mutect2, varscan2
- RTF1 | c.447C>T p.A149= | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as COSV63172874; called by muse, mutect2, varscan2
- RYR1 | c.5928C>T p.R1976= | Silent (SNP) | VAF 12/48 reads (25%) | catalogued as COSV62088673; called by muse, mutect2, varscan2
- SARDH | c.417G>A p.E139= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as COSV53831858, COSV53834342; called by muse, mutect2, varscan2
- SEMA6D | c.2766C>T p.V922= (on ENST00000316364 / NM_153618.2; = p.V860= on NM_020858.2) | Silent (SNP) | VAF 28/123 reads (23%) | catalogued as COSV60372620; called by muse, mutect2, varscan2
- SERPINF2 | c.1233G>A p.V411= | Silent (SNP) | VAF 114/165 reads (69%) | catalogued as COSV60663492; called by muse, mutect2, varscan2
- SHANK3 | c.1791C>T p.F597= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99436509; called by muse, varscan2
- SIGLEC1 | c.4311C>T p.I1437= | Silent (SNP) | VAF 20/110 reads (18%) | catalogued as rs754759740, COSV52458517; called by muse, mutect2, varscan2
- SLC12A4 | c.468C>T p.I156= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs373425859, COSV57925283; called by muse, mutect2, varscan2
- SLC17A3 | c.156G>A p.T52= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as rs781745859, COSV57759410; called by muse, mutect2, varscan2
- SLC38A8 | c.945C>T p.F315= | Silent (SNP) | VAF 19/41 reads (46%) | catalogued as rs1345623470, COSV55304319; called by muse, mutect2, varscan2
- SNX20 | c.147G>A p.L49= | Silent (SNP) | VAF 28/96 reads (29%) | catalogued as COSV56056568; called by muse, mutect2, varscan2
- SPANXN2 | c.183G>A p.T61= | Silent (SNP) | VAF 62/121 reads (51%) | catalogued as rs782774590, COSV65127684; called by muse, varscan2
- SPTAN1 | c.5376C>T p.Y1792= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as rs146418243; called by muse, mutect2, varscan2
- SRGAP2 | c.2934C>T p.P978= (on ENST00000624873 / NM_001170637.4; = p.P979= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV55333042; called by muse, mutect2, varscan2
- STAB2 | c.1266G>A p.E422= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as COSV66334024; called by muse, mutect2, varscan2
- SYCP2L | c.2346G>A p.K782= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV51649859; called by muse, mutect2, varscan2
- TBXT | c.1155C>T p.P385= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV51616111, COSV99752838; called by muse, mutect2, varscan2
- TECTA | c.2982C>T p.I994= | Silent (SNP) | VAF 28/58 reads (48%) | catalogued as COSV50687821; called by muse, mutect2, varscan2
- TENM1 | c.7098C>T p.F2366= | Silent (SNP) | VAF 29/60 reads (48%) | catalogued as COSV64424949; called by muse, mutect2, varscan2
- THEMIS | c.1674G>A p.P558= | Silent (SNP) | VAF 43/80 reads (54%) | catalogued as rs866930287, COSV64069210; called by muse, mutect2, varscan2
- TINAG | c.156C>T p.F52= | Silent (SNP) | VAF 51/152 reads (34%) | catalogued as COSV52505058; called by muse, mutect2, varscan2
- TMEM104 | c.1143G>A p.K381= | Silent (SNP) | VAF 58/152 reads (38%) | catalogued as COSV59107842; called by muse, mutect2, varscan2
- TMEM211 | c.378C>T p.I126= (on ENST00000423535; = p.I55= on NM_001001663.3) | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs765272148, COSV66953991; called by muse, mutect2, varscan2
- TMTC4 | c.822C>T p.T274= (on ENST00000376234 / NM_001350577.2; = p.T293= on NM_032813.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/118 reads (26%) | catalogued as COSV60891302; called by muse, mutect2, varscan2
- TNFRSF10A | c.681C>T p.I227= | Silent (SNP) | VAF 39/164 reads (24%) | catalogued as rs761290876, COSV55324427; called by muse, mutect2, varscan2
- TRAV1-2 | c.78G>A p.E26= | Silent (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- TRPM1 | c.3912C>T p.F1304= | Silent (SNP) | VAF 27/110 reads (25%) | catalogued as rs1222310468, COSV56630369; called by muse, mutect2, varscan2
- TRPM6 | c.2487G>A p.R829= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as COSV62502786; called by muse, mutect2, varscan2
- TSKS | c.1389C>T p.S463= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as COSV55872781; called by muse, mutect2, varscan2
- TTN | c.91674C>T p.V30558= (on ENST00000591111; = p.V23134= on NM_003319.4) | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV59883570; called by muse, mutect2, varscan2
- TTN | c.13161G>A p.R4387= (on ENST00000591111; = p.R4341= on NM_003319.4) | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV59883629; called by muse, mutect2, varscan2
- UGT1A6 | c.1317C>T p.I439= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV59381519; called by muse, mutect2
- UHRF1BP1L | c.1971C>T p.F657= | Silent (SNP) | VAF 20/36 reads (56%) | catalogued as COSV54434483; called by muse, mutect2, varscan2
- UIMC1 | c.720T>C p.G240= | Silent (SNP) | VAF 50/139 reads (36%) | catalogued as COSV65893089; called by muse, mutect2, varscan2
- USP11 | c.1941C>T p.N647= (on ENST00000218348; = p.N604= on NM_001371072.1) | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs137968498, COSV54472345; called by muse, mutect2, varscan2
- VPS13D | c.6531G>A p.K2177= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as rs368008383; called by muse, mutect2, varscan2
- VSIG4 | c.19C>T p.L7= | Silent (SNP) | VAF 25/41 reads (61%) | catalogued as COSV66073117; called by muse, mutect2, varscan2
- VWA3B | c.3204C>T p.F1068= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV69034106; called by muse, mutect2, varscan2
- XDH | c.522G>A p.G174= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as rs759462982, COSV65146846; called by muse, mutect2, varscan2
- ZBED9 | c.3288G>A p.V1096= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV71729158, COSV71729392; called by muse, mutect2, varscan2
- ZFHX4 | c.9042G>A p.V3014= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV50490894; called by muse, mutect2, varscan2
- ZMIZ2 | c.2292C>T p.T764= | Silent (SNP) | VAF 15/83 reads (18%) | catalogued as COSV54805956; called by muse, mutect2, varscan2
- ZNF224 | c.390C>T p.F130= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV61241478; called by muse, mutect2, varscan2
- ZNF483 | c.625C>T p.L209= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV58514493; called by muse, mutect2, varscan2
- ZNF516 | c.135C>T p.F45= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV71586670; called by muse, mutect2, varscan2
- ZNF578 | c.579C>T p.S193= | Silent (SNP) | VAF 36/103 reads (35%) | catalogued as COSV69735922; called by muse, mutect2, varscan2
- ZNF626 | c.285C>T p.F95= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV74128920; called by muse, mutect2, varscan2
- ZNFX1 | c.2109C>T p.F703= | Silent (SNP) | VAF 46/187 reads (25%) | catalogued as COSV65573638; called by muse, mutect2, varscan2
- ADGRE4P | n.1107G>A | RNA (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- ALMS1P1 | chr2:73701080 A>G | 3'Flank (SNP) | VAF 20/73 reads (27%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.2522-3575C>T | Intron (SNP) | VAF 27/116 reads (23%) | catalogued as COSV52766914; called by muse, mutect2, varscan2
- C9orf163 | n.1547C>T | RNA (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- CCDC18 | c.-3+327G>A | Intron (SNP) | VAF 14/43 reads (33%) | catalogued as COSV100159344; called by muse, mutect2, varscan2
- DEPDC5 | c.1870+2279C>T | Intron (SNP) | VAF 44/156 reads (28%) | catalogued as COSV56690898; called by muse, mutect2, varscan2
- HLA-F | chr6:29726956 A>T | 3'Flank (SNP) | VAF 44/221 reads (20%) | catalogued as COSV52574529; called by muse, mutect2, varscan2
- KRT18P23 | chr22:44570565 G>A | 3'Flank (SNP) | VAF 4/35 reads (11%) | catalogued as rs1184590079; called by muse, mutect2, varscan2
- MIR519B | n.21G>A | RNA (SNP) | VAF 43/129 reads (33%) | catalogued as rs1394539989; called by muse, mutect2, varscan2
- NEBL | c.164+46424C>T | Intron (SNP) | VAF 20/67 reads (30%) | catalogued as rs1480291556, COSV65797737; called by muse, mutect2, varscan2
- OBSCN | c.11660-2591G>A | Intron (SNP) | VAF 62/177 reads (35%) | catalogued as COSV99475000; called by muse, varscan2
- OR1N2 | c.-3G>A | 5'UTR (SNP) | VAF 28/104 reads (27%) | catalogued as COSV65460181; called by muse, mutect2, varscan2
- PARGP1 | n.811C>T | RNA (SNP) | VAF 11/23 reads (48%) | called by muse, mutect2, varscan2
- RBFOX1 | c.996-15713G>A | Intron (SNP) | VAF 34/74 reads (46%) | catalogued as rs868429991, COSV60955310, COSV60977741; called by muse, mutect2, varscan2
- SLC22A20P | n.668C>T | RNA (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- SLC22A20P | n.669C>T | RNA (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- UGT1A6 | c.862-23400C>T | Intron (SNP) | VAF 39/140 reads (28%) | catalogued as COSV59381349; called by muse, mutect2, varscan2
- URB1 | c.664+1181C>T | Intron (SNP) | VAF 14/62 reads (23%) | catalogued as COSV100784043; called by muse, mutect2, varscan2
- ZNF467 | chr7:149777191 C>T | 5'Flank (SNP) | VAF 4/16 reads (25%) | catalogued as rs1330817568, COSV50486387; called by muse, mutect2
- ZNF99 | c.*716C>T | 3'UTR (SNP) | VAF 16/62 reads (26%) | catalogued as COSV68054629, COSV68055914; called by muse, varscan2
